Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A02X, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A02X-01A (Primary Tumor).

Internal Sample ID

Diagnosis:

This is a lymph node with reactive lesions in I),
in II) - with clinical indication of position - a rectal carcinoma, moderately differentiated,
G2 - with infiltration of the muscularis, pT2, L1, V1,
with fine resection margins and free lymph nodes - pN0 and
a free anastomosis ring in III)

Tumor classification:

ICDO-DA M-8140/3,
G2,
pT2, L1, V1, pN0

ICD-0-3

Path - carcinoma, NOS 8010/3

CQCF - adenocarcinoma, NOS 8140/3

Site: rectum C20.9 Lu 3/31/11

The tumor was completely removed locally.

KMD *3/31/11*

Source: NCI Genomic Data Commons file e7d6a62b-c8e1-4e53-a02b-e05e52d06e30 (TCGA-AG-A02X.FB82E91C-F5D0-4014-A86F-091A58D0CE4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).